MMRF case MMRF_2273 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b06a2821-fb42-4f79-92ea-75f4e3118c61

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.1 years (25,239 days); Days to last known disease status: 814 days (2.2 years); Days to last follow up: 814 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 266 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 253 days; Days to treatment end: 253 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 1): M Protein 3.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 35.6 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.42 ×10⁹/L; Absolute Neutrophil 2.19 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.32 mmol/L; Calcium 2.53 mmol/L; Albumin 38.6 g/L; Total Protein 9.75 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 0.06 mg/dL.
- Day 86 (ECOG 0): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 7.29 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 2.36 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 7.78 ×10⁹/L; Absolute Neutrophil 6.89 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 2.68 mmol/L; Calcium 2.1 mmol/L; Albumin 39.8 g/L; Total Protein 6.46 g/dL; Glucose 7.98 mmol/L.
- Day 184 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 1.88 g/L; Immunoglobulin M 0.63 g/L; Beta 2 Microglobulin 2.58 µg/mL; Lactate Dehydrogenase 4.7 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 8.57 ×10⁹/L; Absolute Neutrophil 6.54 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 77.8 µmol/L; Calcium 2.23 mmol/L; Albumin 38.8 g/L; Total Protein 6.82 g/dL; Glucose 9.46 mmol/L.
- Day 273 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 7.16 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2.75 µg/mL; Hemoglobin 8 mmol/L; Leukocytes 4.22 ×10⁹/L; Absolute Neutrophil 1.38 ×10⁹/L; Platelets 34.3 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 0.821 mmol/L; Calcium 2.33 mmol/L; Albumin 39.1 g/L; Total Protein 6.8 g/dL; Glucose 6.33 mmol/L.
- Day 345 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 6.46 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.23 ×10⁹/L; Absolute Neutrophil 1.58 ×10⁹/L; Platelets 48 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 1.71 mmol/L; Calcium 2.3 mmol/L; Albumin 41.6 g/L; Total Protein 6.21 g/dL; Glucose 4.95 mmol/L.
- Day 457 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 147 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 9.65 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 5.09 µg/mL; Lactate Dehydrogenase 14.1 µkat/L; Hemoglobin 5.51 mmol/L; Leukocytes 4.86 ×10⁹/L; Absolute Neutrophil 2.81 ×10⁹/L; Platelets 87.4 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.64 mmol/L; Calcium 2.33 mmol/L; Albumin 39.9 g/L; Total Protein 6.56 g/dL; Glucose 5.39 mmol/L.
- Day 527 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 9.94 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 4.94 µg/mL; Lactate Dehydrogenase 4.03 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.49 ×10⁹/L; Absolute Neutrophil 1.56 ×10⁹/L; Platelets 92.2 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 2.36 mmol/L; Calcium 2.3 mmol/L; Albumin 42.9 g/L; Total Protein 6.59 g/dL; Glucose 4.79 mmol/L.
- Day 604 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 3.51 µg/mL; Lactate Dehydrogenase 5.27 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.41 ×10⁹/L; Absolute Neutrophil 2.04 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 1.89 mmol/L; Glucose 4.51 mmol/L.
- Day 730 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.25 mg/dL; Immunoglobulin G 19 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.94 g/L; Beta 2 Microglobulin 3.44 µg/mL; Lactate Dehydrogenase 4.38 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.59 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 1.82 mmol/L; Calcium 2.38 mmol/L; Albumin 43.5 g/L; Total Protein 7.68 g/dL; Glucose 5.34 mmol/L.
- Day 814 (ECOG 0): M Protein 0 g/dL; Lactate Dehydrogenase 4.97 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.97 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 70.7 µmol/L; Calcium 2.45 mmol/L; Albumin 42.4 g/L; Total Protein 7.82 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -3: Weight: 60 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_2273_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2273_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
